Gene-level copy-number profile of tumor specimen TCGA-D1-A3JQ-01A from TCGA case TCGA-D1-A3JQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.0 years (22,297 days).
Specimen TCGA-D1-A3JQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.4e3bbb25-a4de-4bbb-b500-c98089fdce7b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D1-A3JQ-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/18104f3e-5b22-43cf-a5e5-4af1057fd6e2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 867; copy number 2: 7,960; copy number 3: 22,507; copy number 4: 24,886; copy number 5: 1,702; copy number 6: 405; copy number 7: 198; copy number 8: 1,024; copy number 9: 195; copy number 10: 69.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D1-A3JQ-01A-11D-A227-01): tumor purity 0.79, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 264 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:35,176,378–37,634,892, 66 genes, copy number 9 (broad region; genes not listed).
- chr19:20,553,792–20,661,583, 1 gene, copy number 9 (within-gene range 5–9): AC010636.2.
- chr19:20,611,559–22,914,340, 107 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr19:29,665,459–34,066,283, 90 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
